Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA36, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA36-01A (Primary Tumor).

Female
Surgery Date:

DIAGNOSIS:

Liver, segment IVB, and gallbladder, resection: Invasive grade 3 (of 4) cholangiocarcinoma forming a hilar mass (10.0 x 9.4 x 7.0 cm). The tumor invades into the wall of the gallbladder. The gallbladder mucosa shows cholesterolosis. The surgical margins are negative

Omentum, biopsy: Metastatic cholangiocarcinoma.

Soft tissue, peri duodenal region, excision: Metastatic cholangiocarcinoma.

ICD-O-3

Cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct C22.1

9/23/14

Source: NCI Genomic Data Commons file 0dfc823f-1f3b-4eeb-a24a-7c53055dfcda (TCGA-W5-AA36.6EC57D32-953A-4B46-AF10-A3AFCF636ED4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).